Somatic mutation profile of tumor specimen BA2629D (aliquot aq-BA2629D) from BEATAML1.0 case 2486, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.6 years (22,504 days).
Specimen BA2629D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80ac1a12-8180-45a6-bada-acccbec64ff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2878D (Solid Tissue Normal), aliquot aq-BA2878D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bdd2732-9684-4a6c-9900-be5d71e64bcc

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.10745C>G p.S3582C (on ENST00000297405 / NM_001363185.1; = p.S3413C on NM_052900.3) | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52108103; called by muse, varscan2
- POLR1A | c.3568G>A p.D1190N | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as rs536089000; called by muse, mutect2, varscan2
- ASPG | c.1579C>A p.L527M | Missense Mutation (SNP) | VAF 2/22 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.366); called by muse, mutect2
- FOSL2 | c.461C>A p.A154E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- OPN4 | c.5A>T p.N2I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- POU5F1B | c.195G>T p.P65= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV66967032; called by muse, mutect2
- DYNLRB1 | chr20:34516417 T>C | 5'Flank (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
